Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5325, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5325-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Nck: left neck level 1
2. Nck: left neck level 2
3. Nck: left neck level 3
4. Nck: left neck level 4
5. Soft Tissue: left hemiglossectomy - lörög stitich anterior, short stitich superior
6. Soft Tissue: anterior margin - QS
7. Soft Tissue: deep margin - QS
8. Soft Tissue: superior margin - QS
9. Soft Tissue: inferior margin - QS
10. Soft Tissue: posterior margin - QS

Diagnosis

1. Left neck level I lymph node.
Three lymph nodes negative for tumor (0/3).
Submandibular gland with no pathologic changes.
2. Left neck level II lymph node.
Four lymph nodes negative for tumor (0/4).
3. Left neck level III lymph node.
Seven lymph nodes negative for tumor (0/7).
4. Left neck level IV lymph node.
Eight lymph nodes negative for tumor (0/8).
5. Oral cavity; tongue; left hemiglossectomy.
Squamous cell carcinoma, moderately differentiated.
- a. Tumor maximum diameter 1.5 cm.
- b. Tumor thickness 0.8 cm.
- c. No peri-neural invasion.
- d. No lymphatic/vascular invasion.
- e. Margins negative for tumor.
6. Anterior margin.
Squamous mucosa negative for tumor.
7. Deep margin.
Skeletal muscle negative for tumor.

[page 2 of 3]
Surgical Pathology Consultation Report

8. Superior margin.
Squamous mucosa negative for tumor.

9. Inferior margin.
Squamous mucosa negative for tumor.

10. Posterior margin.
Squamous mucosa negative for tumor.

Synoptic Data

Specimen Type:	Resection:left hemiglossectomy
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 1.5 cm Cannot be determined Tumor thickness: 0.8 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	None identified
Margins:	Margins uninvolved by tumor - Distance of tumor from closest margin: 0.5 cm Margins: Medial/deep
Pathologic Staging (pTNM):	pT1: Tumor of lip or oral cavity 2 cm or less in greatest dimension pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 22 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

Gross Description

1. The specimen is labeled with the patient's name and "Neck: Left neck level 1". It consists of a submandibular gland and fibroadipose tissue measuring 5.0 x 4.0 x 1.8 cm. The submandibular gland measures 4.0 x 3.0 x 1.4 cm and is unremarkable. Multiple lymph nodes ranging from 0.5 to 1.2 cm are identified. Representative sections are submitted.

1A submandibular gland
1B one lymph node
1C two lymph nodes

2. The specimen is labeled with the patient's name and "Neck: Left neck level 2". It consists of portion of fibroadipose tissue measuring 6.0 x 3.0 x 1.2 cm. Multiple lymph nodes ranging from 0.3 to 1.0 cm are identified. Representative sections are submitted.

2A multiple lymph nodes

3. The specimen is labeled with the patient's name and "Neck: Left neck level 3". It consists of portion of fibroadipose tissue measuring 7.8 x 4.0 x 1.2 cm. Multiple lymph nodes ranging from 0.7 to 1.5 cm are identified. Representative sections are submitted.

3A-3B one lymph node each
3C multiple lymph nodes

[page 3 of 3]
Surgical Pathology Consultation Report

4. The specimen is labeled with the patient's name and "Neck: Left neck level 4". It consists of portion of fibroadipose tissue measuring 4.5 x 3.0 x 1.9 cm. Multiple lymph nodes ranging from 0.3 to 1.2 cm are identified. Representative sections are submitted.

4A one lymph node

4B-4C multiple lymph nodes each

5. The specimen is labeled the patient's name and as "Soft Tissue: Left hemiglossectomy-long stitch anterior, short stitch superior". It consists of an oriented portion of left tongue measuring 3.5 SI x 2.0 ML x 4.5 AP cm. There is a well circumscribed tumor involving the lateral surface of the tongue. The tumor measures 1.3 cm SI x 0.8 cm ML x 1.5 cm AP. The tumor is solid and tan-brown. It is located at 0.8 cm from the superior margin, 1.1 cm from the inferior margin, 0.5 cm from the medial/deep margin, 1.0 cm from the anterior margin, and 1.4 cm from the posterior margin. The remaining tongue mucosa is unremarkable. Representative sections are submitted.

5A superior margin

5B inferior margin

5C anterior margin

5D posterior margin

5E-5G tumor with deep margin

5H normal tongue

6. The specimen is labeled with the patient's name and "Soft Tissue: Anterior margin". It consists of a fragment of tissue measuring 0.5 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and "Soft Tissue: Deep margin". It consists of a fragment of tissue measuring 0.5 x 0.5 x 0.5 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and "Soft Tissue: Superior margin". It consists of a fragment of tissue measuring 1.0 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and "Soft Tissue: Inferior margin". It consists of a fragment of tissue measuring 1.0 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

9A frozen section control

10. The specimen is labeled with the patient's name and as "Soft Tissue: Posterior margin". It consists of a fragment of tissue measuring 0.5 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

10A frozen section control

Quick Section Diagnosis

6A,7A,8A,9A,10A- Negative for malignancy (x5).

Source: NCI Genomic Data Commons file 9b4db5bb-b7f9-438e-8c62-8c16095b06ad (TCGA-CQ-5325.0B471DF4-CA7A-4830-8C7D-5FADC02501A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).